Somatic mutation profile of tumor specimen 0DUFE9 from CCDI case PBCKXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,553 days).
Specimen 0DUFE9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74be0304-9bf2-4202-a77a-bc89c5374e47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUFDA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc83fc6e-57d0-4d9a-9f4b-0819828efc73

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF14 | c.3754T>G p.F1252V | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1558049859; called by muse, mutect2, varscan2
- NRK | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 134/234 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs202127779, COSV54603611; called by muse, mutect2, varscan2
- WWP1 | c.2300G>C p.R767P | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55365881; called by muse, mutect2
- OR4C13 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 34/483 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PRICKLE4 | c.-536A>T | 5'UTR (SNP) | VAF 136/289 reads (47%) | called by muse, mutect2, varscan2
